Somatic mutation profile of tumor specimen TCGA-QK-A64Z-01A (aliquot TCGA-QK-A64Z-01A-11D-A30E-08) from TCGA case TCGA-QK-A64Z, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 79.5 years (29,037 days).
Specimen TCGA-QK-A64Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12e48211-7aab-4fd6-b46d-8a658df9d0a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A64Z-10A (Blood Derived Normal), aliquot TCGA-QK-A64Z-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82a9ceb9-6ce4-47d3-bf37-8d4b96857903

The open-access MAF lists 91 somatic variants for this specimen: 62 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 27, Nonsense Mutation 7, 3'UTR 1, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADPGK | c.842T>A p.V281D | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100295350; called by muse, mutect2
- AKAP9 | c.718A>T p.I240F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100662630, COSV100662936; called by muse, mutect2, varscan2
- ARMCX3 | c.820C>G p.P274A | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100362322; called by muse, mutect2, varscan2
- BRD9 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs141776263; called by muse, varscan2
- BRWD3 | c.4173T>A p.Y1391* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100956433; called by muse, mutect2, varscan2
- CACNA2D1 | c.2690C>G p.S897C (on ENST00000356253 / NM_001366867.1; = p.S885C on NM_000722.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV100667113; called by muse, mutect2, varscan2
- CASP8 | c.344C>A p.S115* (on ENST00000432109 / NM_033355.3; = p.S147* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV51847755, COSV51852205; called by muse, mutect2, varscan2
- CCDC24 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs745423717, COSV100530914; called by muse, mutect2, varscan2
- CDC23 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.405); catalogued as COSV67508297; called by muse, mutect2, varscan2
- CDH20 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as COSV99406371; called by muse, mutect2, varscan2
- CHUK | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs777268657, COSV100957265; called by muse, mutect2, varscan2
- CMSS1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs142737434, COSV70439780; called by muse, mutect2, varscan2
- EPSTI1 | c.310C>G p.H104D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV100553147; called by muse, mutect2, varscan2
- FAM47B | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1229137762, COSV61456239; called by muse, mutect2, varscan2
- FAT1 | c.10198C>T p.R3400* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs778150447, COSV101499250; called by muse, mutect2, varscan2
- FAT1 | c.7303C>T p.H2435Y | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs1366754016, COSV101499604; called by muse, mutect2, varscan2
- FLG2 | c.6037G>A p.G2013R | Missense Mutation (SNP) | VAF 113/482 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs987021120, COSV101166137; called by muse, mutect2, varscan2
- FOXD4L5 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.277); catalogued as rs1182120702; called by mutect2, varscan2
- FOXK1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61066683; called by muse, mutect2, varscan2
- H4C8 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99175510; called by muse, mutect2, varscan2
- HEATR6 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV99482572; called by muse, mutect2, varscan2
- HMGB2 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99632806; called by muse, mutect2, varscan2
- HOXD12 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV101184334; called by muse, mutect2
- KALRN | c.6340G>C p.E2114Q (on ENST00000360013 / NM_001024660.4; = p.E417Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV99362775; called by muse, mutect2
- KCNQ4 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV61275446; called by muse, mutect2, varscan2
- KRT23 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52929285, COSV99266346; called by muse, mutect2, varscan2
- LRP2 | c.6766G>A p.D2256N | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99789957; called by muse, mutect2, varscan2
- LY6G5C | c.427G>A p.E143K (on ENST00000375863; = p.E68K on NM_025262.3) | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV101020850; called by muse, mutect2
- MANBA | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99899100; called by muse, mutect2, varscan2
- MAP2K5 | c.1115T>A p.L372Q (on ENST00000178640 / NM_145160.3; = p.L362Q on NM_002757.4) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99462037; called by muse, mutect2, varscan2
- MTSS2 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851980; called by muse, mutect2, varscan2
- NFATC2 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs779382116, COSV65352933; called by muse, mutect2, varscan2
- NIN | c.2837G>C p.R946T | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV99814979; called by muse, mutect2, varscan2
- NIN | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99814987; called by muse, mutect2, varscan2
- NOTCH4 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.841); catalogued as rs779257242, COSV100900952; called by muse, mutect2, varscan2
- OR52R1 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617789; called by muse, mutect2
- ORC3 | c.1682G>A p.C561Y | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100006216; called by muse, mutect2, varscan2
- PCDHA4 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100793690; called by muse, mutect2, varscan2
- PDE1C | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs1181737020, COSV58506466; called by muse, mutect2
- PDPR | c.2069A>G p.Y690C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99848776; called by muse, mutect2, varscan2
- PNMA2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs774422018, COSV72908495; called by muse, mutect2, varscan2
- PRELID3B | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV99718030; called by muse, mutect2, varscan2
- PTCHD4 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.118); catalogued as COSV100261474, COSV59798068; called by muse, mutect2, varscan2
- RNF213 | c.10909G>A p.A3637T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100301312; called by muse, mutect2, varscan2
- RPLP0 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV99935453; called by muse, mutect2
- RRP12 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs116818150; called by muse, mutect2
- SLC13A1 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99521390; called by muse, mutect2, varscan2
- SLITRK3 | c.17C>G p.A6G | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53845518, COSV53852547, COSV99579940; called by muse, mutect2, varscan2
- SV2A | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100975245; called by muse, mutect2, varscan2
- TCOF1 | c.3860C>G p.S1287* (on ENST00000377797 / NM_001135243.1; = p.S1210* on NM_000356.4) | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV100078211; called by muse, mutect2, varscan2
- THBS3 | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100857695; called by muse, mutect2, varscan2
- TMC4 | c.1474C>G p.L492V (on ENST00000617472 / NM_001145303.3; = p.L486V on NM_144686.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99714119; called by muse, mutect2, varscan2
- TMEM14B | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as rs1561913133, COSV101077488; called by muse, mutect2
- TOE1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100517663; called by muse, mutect2, varscan2
- TRPM6 | c.1304G>A p.W435* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100666892; called by muse, mutect2, varscan2
- WDR59 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs772939609, COSV100049661; called by muse, mutect2, varscan2
- XKR4 | c.753C>G p.C251W | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100533769, COSV59326918; called by muse, mutect2, varscan2
- ZNF214 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99547613, COSV99547702; called by muse, mutect2, varscan2
- ZNF257 | c.1180C>A p.H394N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101448155, COSV71306235; called by muse, mutect2, varscan2
- ARMC10 | c.929del p.F310Sfs*12 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- ADRA2C | c.591C>T p.A197= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1216691211; called by mutect2, varscan2
- ASIC3 | c.1539C>T p.A513= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as rs370089221, COSV52522746; called by muse, mutect2, varscan2
- CFAP43 | c.3918C>G p.L1306= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1234602526, COSV100829463; called by muse, mutect2, varscan2
- CREB3 | c.378G>A p.E126= | Silent (SNP) | VAF 130/492 reads (26%) | catalogued as rs1563950930, COSV100148143; called by muse, mutect2, varscan2
- FKTN | c.690C>G p.L230= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99795555; called by muse, mutect2, varscan2
- GABRE | c.441G>C p.V147= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV100944356; called by muse, mutect2, varscan2
- HTT | c.510C>G p.L170= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV100751155; called by muse, mutect2, varscan2
- LHX9 | c.198G>A p.E66= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as COSV100436039, COSV61327980; called by muse, mutect2, varscan2
- MACF1 | c.13177T>C p.L4393= (on ENST00000372915; = p.L2326= on NM_012090.5) | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99246372; called by muse, mutect2, varscan2
- MAP2 | c.5265C>T p.V1755= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99561471; called by muse, mutect2
- MUC16 | c.21222C>T p.L7074= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV101201196; called by muse, mutect2, varscan2
- MYO1F | c.2010G>A p.G670= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV100597010, COSV57792410; called by muse, mutect2, varscan2
- NALCN | c.4323G>T p.L1441= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99217187; called by muse, mutect2, varscan2
- NDUFA9 | c.1113G>C p.P371= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99866014; called by muse, mutect2, varscan2
- NOTCH4 | c.3708A>G p.E1236= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100900953; called by muse, mutect2, varscan2
- OR11L1 | c.492C>T p.S164= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as rs750973577, COSV100869379; called by muse, mutect2, varscan2
- OR4K5 | c.561T>G p.L187= | Silent (SNP) | VAF 18/382 reads (5%) | catalogued as COSV100262583; called by muse, mutect2
- PER2 | c.2619C>T p.H873= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs376874446; called by muse, mutect2, varscan2
- SCN3A | c.720G>C p.L240= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV51826152, COSV99328257; called by muse, mutect2, varscan2
- TBXA2R | c.612C>T p.G204= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs201736798, COSV64343049; called by muse, mutect2, varscan2
- TMEM121 | c.240C>T p.F80= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101180080; called by muse, mutect2, varscan2
- TRPA1 | c.2634C>A p.I878= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100085025; called by muse, mutect2, varscan2
- TTN | c.45849T>C p.Y15283= (on ENST00000591111; = p.Y7859= on NM_003319.4) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100626563; called by muse, mutect2, varscan2
- UBN2 | c.2403G>A p.L801= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99944367; called by muse, mutect2, varscan2
- UGT1A1 | c.642C>T p.L214= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as COSV100530867; called by muse, mutect2, varscan2
- ZNF519 | c.1062C>A p.G354= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV101645590; called by muse, mutect2, varscan2
- ZNF611 | c.741G>A p.R247= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as COSV100160546; called by muse, mutect2, varscan2
- ISCU | c.115-138G>C | Intron (SNP) | VAF 33/157 reads (21%) | catalogued as COSV99934365; called by muse, mutect2, varscan2
- SNX4 | c.*2_*10del | 3'UTR (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
